Surgical pathology report (de-identified scan), TCGA case TCGA-27-1838, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1838-01A (Primary Tumor).

Ref. Number

Gender

Birth date

Tumor site

Left occipito-temporal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file 7d5f0346-c8ab-4878-a986-1b28b0c3093c (TCGA-27-1838.91FBAFB9-E95B-486C-8029-24E0C77F6B57.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).